Surgical pathology report (de-identified scan), TCGA case TCGA-DV-5576, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-5576-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

1. "Tumor #1", left kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, predominantly cystic, Fuhrman nuclear grade II.
2. "Tumor #2", left kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, predominantly cystic, Fuhrman nuclear grade II.
3. "Tumor #3", left kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, predominantly cystic, Fuhrman nuclear grade II.

NOTE:

CLINICAL INFORMATION: Allocate Order to Protocol: [REDACTED] Brief Clinical History: [REDACTED]
[REDACTED] with VHL and a left renal mass Specimen Taken For Protocol: [REDACTED]
- Yes

PROCEDURE: Pre-Operative Diagnosis: left renal mass Post-Operative Diagnosis:
left renal mass Operative Findings: left renal mass

SPECIMENS SUBMITTED: 1. TUMOR, # 1
2. TUMOR, # 2
3. TUMOR, # 3

GROSS DESCRIPTION: Received are 3 formalin-filled containers labeled with the patient's name, medical record number, and further specified as follows:

Patient Identification

[page 2 of 2]
1. "Tumor #1". The specimen consists of a red/tan soft tissue fragment measuring 0.6 x 0.5 x 0.2 cm. The specimen is serially sectioned and entirely submitted in a white cassette labeled [redacted] for permanent processing.

2. "Tumor #2". The specimen consists of a red/tan soft tissue fragment measuring 1.3 x 0.9 x 0.5 cm. The specimen appears cystic. The specimen is serially sectioned and entirely submitted in a white cassette labeled [redacted] for permanent processing.

3. "Tumor #3". The specimen consists of a red/tan soft tissue mass measuring 2.5 x 2.4 x 1.0 cm that appears to have been bisected and cystic. The specimen is serially sectioned entirely submitted in white cassettes labeled [redacted] for permanent processing.

No consultants

Patient Identification

Source: NCI Genomic Data Commons file 7f2d7d4d-4a85-45b8-b7e5-edf1e7ae562e (TCGA-DV-5576.D0577E2D-BA55-4E6E-ACBA-C78EB9736723.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).